Gene-level copy-number profile of tumor specimen TCGA-A7-A26I-01A from TCGA case TCGA-A7-A26I, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 65.6 years (23,948 days).
Specimen TCGA-A7-A26I-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.eaf26eaa-106e-46e3-9963-c6185c6ec4d7.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A26I-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aacc7d7b-f1da-4f53-9cc2-aa403fce89e6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 814; copy number 2: 23,874; copy number 3: 15,587; copy number 4: 13,223; copy number 5: 3,355; copy number 6: 1,122; copy number 7: 8; copy number 8: 545; copy number 9: 292; copy number 10: 226; copy number 11: 243; copy number 14: 275; copy number 15: 9; copy number 16: 67; copy number 17: 55; copy number 18: 37; copy number 19: 63; copy number 22: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A26I-01A-11D-A166-01): tumor purity 0.55, ploidy 3.09, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:41,246,599–41,962,130, 5 genes (within-gene range 0–2): ULK4, AC099537.1, RN7SKP58, ATP6V0E1P2, Y_RNA.
- chr14:102,770,040–102,774,791, 1 gene: AL132801.1.
- chr16:3,930,806–4,116,442, 3 genes (within-gene range 0–3): LINC02861, ADCY9, AC005736.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,385 genes in 31 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:147,019,656–148,255,012, 44 genes, copy number 19 (within-gene range 2–19): AC244394.2, AC244394.1, RNU1-151P, SSBL4P, RNVU1-8, NBPF13P, PRKAB2, PDIA3P1, AC242426.2, FMO5, CCT8P1, RPL7AP15, CHD1L, LINC00624, AC242426.1, OR13Z1P, Y_RNA, OR13Z2P, OR13Z3P, BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2.
- chr1:149,048,576–164,980,137, 701 genes, copy number 5–17 (broad region; genes not listed).
- chr1:165,210,627–165,219,104, 2 genes, copy number 6: LMX1A-AS2, LMX1A-AS1.
- chr1:169,588,849–178,921,841, 170 genes, copy number 6 (broad region; genes not listed).
- chr1:183,460,874–185,628,944, 46 genes, copy number 5–7 (within-gene range 3–7): SMG7-AS1, SMG7, NCF2, AL137800.1, ARPC5, RGL1, APOBEC4, AL157899.1, AL590422.1, COLGALT2, TSEN15, AL158011.1, Y_RNA, Y_RNA, AL445228.1, RN7SL654P, AL445228.2, C1orf21, AL078645.1, AL078645.2, AL713852.1, AL713852.2, EDEM3, NIBAN1, RNU7-13P, LINC01633, RNA5SP72, RNF2, FTH1P25, TRMT1L, SWT1, RPL22P24, RPL5P5, Y_RNA, Y_RNA, AL356273.1, Y_RNA, AL356273.2, AL356273.3, IVNS1ABP, AL078644.1, GS1-279B7.1, RNU7-183P, MCRIP2P2, AL133383.2, LINC01350.
- chr1:219,968,600–221,563,653, 40 genes, copy number 5 (within-gene range 3–5): EPRS1, BPNT1, IARS2, MIR215, MIR194-1, RPS15AP12, RAB3GAP2, MIR664A, SNORA36B, SNX2P1, KF455155.1, MORF4L1P1, AURKAP1, XRCC6P3, AL451081.2, AL451081.1, AC096644.3, AC096644.2, AC096644.1, PRELID3BP1, LINC02779, MARK1, RN7SL464P, HDAC1P2, C1orf115, MTARC2, MTARC1, AL445423.3, RNU6ATAC35P, AL445423.2, AL445423.1, LINC01352, HLX-AS1, HLX, AL445466.1, LINC02817, AL360013.2, AL360013.3, AL360013.1, AL360013.4.
- chr1:225,401,502–244,731,586, 444 genes, copy number 5 (broad region; genes not listed).
- chr2:43,001,355–43,228,855, 9 genes, copy number 6: AC016735.1, LINC01819, LINC02590, RNU6-242P, LINC02580, AC010883.2, AC010883.3, ZFP36L2, LINC01126.
- chr2:76,445,079–78,599,406, 18 genes, copy number 5: RN7SKP203, RN7SKP164, AC068616.2, AC068616.3, AC068616.1, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1, AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1.
- chr2:78,882,447–78,882,734, 2 genes, copy number 5: RNU6-827P, RNU6-812P.
- chr3:175,079,307–175,115,242, 1 gene, copy number 5: NAALADL2-AS3.
- chr4:47,831,330–49,062,081, 22 genes, copy number 5 (within-gene range 2–5): AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr6:41,158,506–63,779,336, 375 genes, copy number 8–19 (broad region; genes not listed).
- chr6:63,797,189–63,857,769, 3 genes, copy number 19: AL354719.1, SCAT8, GCNT1P4.
- chr6:148,017,422–150,405,969, 65 genes, copy number 16 (broad region; genes not listed).
- chr6:151,319,635–151,319,950, 1 gene, copy number 10: RN7SKP268.
- chr7:57,119,614–64,300,818, 144 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:72,822,894–159,233,377, 1,702 genes, copy number 5 (broad region; genes not listed).
- chr9:68,328,308–68,531,061, 1 gene, copy number 10 (within-gene range 4–10): PGM5.
- chr9:68,426,843–69,906,227, 25 genes, copy number 10: AL161457.1, TMEM252, TMEM252-DT, LINC01506, AL353616.1, PIP5K1B, FAM122A, AL354794.2, AL354794.1, RNU6-820P, PRKACG, AL358113.1, FXN, AL162730.1, TJP2, BANCR, FAM189A2, APBA1, AL355140.1, AL353693.1, AL162412.1, PTAR1, C9orf135-DT, C9orf135, RN7SL570P.
- chr9:86,414,201–91,427,144, 94 genes, copy number 9–10 (broad region; genes not listed).
- chr9:119,935,053–120,894,896, 12 genes, copy number 5: LINC01613, AL441989.1, MIR147A, CDK5RAP2, MEGF9, AHCYP2, FBXW2, B3GNT10, AL161911.1, PSMD5, CUTALP, PHF19.
- chr10:44,712–38,762,491, 674 genes, copy number 6–9 (broad region; genes not listed).
- chr10:118,241,468–118,755,249, 8 genes, copy number 5 (within-gene range 3–5): AL354863.1, FAM204A, LINC00867, SLC25A18P1, PRLHR, TOMM22P5, CACUL1, AL139407.1.
- chr10:119,029,714–121,185,966, 42 genes, copy number 5: NANOS1, EIF3A, SNORA19, AL355598.1, AL355598.2, DENND10, SFXN4, PRDX3, GRK5, GRK5-IT1, RN7SL749P, AL583824.1, MIR4681, RGS10, AC012468.1, TIAL1, RAD1P1, RPS8P4, BAG3, TXNP1, INPP5F, RN7SL846P, PHACTR2P1, AL133461.1, MCMBP, SEC23IP, MIR4682, NACAP2, AL355298.1, RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153.
- chr11:133,064,697–133,068,129, 1 gene, copy number 6: AP004782.1.
- chr16:70,802,084–71,230,722, 4 genes, copy number 9 (within-gene range 2–9): HYDIN, RNU6ATAC25P, AC138625.2, AC138625.1.
- chr18:6,374,361–6,642,478, 9 genes, copy number 15: MIR4317, AP005060.1, RNU6-349P, RPL6P27, AP005202.2, LINC01387, AP005202.1, RN7SL282P, AP005205.1.
- chr19:27,638,483–40,912,357, 508 genes, copy number 5–22 (within-gene range 4–34) (broad region; genes not listed).
- chr19:44,023,118–44,993,341, 56 genes, copy number 10 (within-gene range 4–10): AC067968.2, ZNF222, AC067968.1, ZNF223, ZNF284, RNU6-902P, ZNF224, AC021092.1, ZNF225, ZNF234, AC138470.2, ZNF226, ZNF227, ZNF235, AC138470.1, ZNF233, AC138473.1, NDUFA3P1, ZNF112, AC245748.1, ZNF285, AC245748.2, ZNF229, ZNF285B, ZNF180, CEACAM20, AC245748.3, CEACAM22P, AC243964.1, IGSF23, AC243964.3, PVR, MIR4531, CEACAM19, AC243964.4, CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1.
- chr21:42,843,094–46,665,124, 162 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 814. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
